Somatic mutation profile of tumor specimen 1ae5772a-ba49-4c00-b890-7513d0 (aliquot 1ae5772a-ba49-4c00-b890-7513d0_D6_1) from CPTAC case 18BR007, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.0 years (23,359 days).
Specimen 1ae5772a-ba49-4c00-b890-7513d0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c96d9495-e009-4368-840a-42b72b2ffb9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1389064d-3882-462c-ab2d-407775 (Blood Derived Normal), aliquot 1389064d-3882-462c-ab2d-407775_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/802cd012-2ad4-4534-bc75-5e938de67492

The open-access MAF lists 124 somatic variants for this specimen: 84 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 25, Intron 6, Nonsense Mutation 4, 5'Flank 3, Frame Shift Del 3, 3'UTR 2, Splice Site 2, 5'UTR 2, In Frame Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 148/502 reads (29%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376917479; called by muse, mutect2, varscan2
- ADAMTS12 | c.4688T>A p.V1563E | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1404371805; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2771T>G p.V924G | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs541118474; called by muse, mutect2, varscan2
- ADIPOQ | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57859114; called by muse, mutect2
- CTCF | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.981); catalogued as COSV50488430, COSV50498133; called by muse, mutect2, varscan2
- DCTN2 | c.502G>A p.D168N (on ENST00000548249 / NM_001261413.2; = p.D173N on NM_006400.4) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63073113; called by muse, mutect2, varscan2
- F13B | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | catalogued as COSV66375835; called by muse, mutect2
- FST | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as rs748145800, COSV99887381; called by muse, mutect2, varscan2
- GLS2 | c.929+1G>A p.X310_splice | Splice Site (SNP) | VAF 11/83 reads (13%) | catalogued as rs1191485742, COSV57665823; called by muse, mutect2, varscan2
- KLHL34 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1473388915; called by muse, varscan2
- KLHL4 | c.1363A>T p.S455C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV64145126; called by muse, mutect2, varscan2
- LAMA5 | c.6848G>A p.R2283Q | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145203663; called by muse, mutect2
- MIER2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs370555952; called by muse, mutect2, varscan2
- OR51G2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1009951836; called by muse, mutect2, varscan2
- OR6K2 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62743564; called by muse, mutect2, varscan2
- PRDM2 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99341119; called by muse, mutect2, varscan2
- SACS | c.10881C>G p.I3627M | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV66548333; called by muse, mutect2, varscan2
- SYT3 | c.484T>G p.L162V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as COSV58895953; called by mutect2, varscan2
- TRPC4 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV59006610, COSV59012215; called by muse, mutect2
- VWDE | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51727233; called by muse, mutect2, varscan2
- ZMYM2 | c.1382G>C p.G461A | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV67036508; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as COSV53369847; called by muse, mutect2, varscan2
- ZNF541 | c.1945G>T p.G649W | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs567345337, COSV54546141; called by muse, mutect2, varscan2
- ZNF582 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100018886; called by muse, mutect2, varscan2
- ABCA8 | c.4413A>C p.K1471N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- ABI3BP | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM15 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2
- ADGRA2 | c.2812A>C p.I938L | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by mutect2, varscan2
- ADGRG6 | c.3422-1G>T p.X1141_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- ADGRL3 | c.988G>T p.D330Y (on ENST00000506720 / NM_001322402.2; = p.D262Y on NM_015236.6) | Missense Mutation (SNP) | VAF 57/431 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP3 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDR2 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by mutect2, varscan2
- CHST1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNTN4 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COL6A6 | c.5471T>G p.L1824R | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- COLCA2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2
- CYB561D1 | c.304_306del p.L102del | In Frame Del (DEL) | VAF 25/256 reads (10%) | called by mutect2, pindel, varscan2
- CYP4F2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- EHBP1L1 | c.1254_1264delinsA p.S418Rfs*12 | Frame Shift Del (DEL) | VAF 41/240 reads (17%) | called by pindel, varscan2*
- ERCC6L2 | c.4104C>G p.D1368E | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM126A | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FAM166B | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 118/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM2 | c.2871A>C p.L957F | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FUOM | c.394A>C p.T132P | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GANAB | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- GRIK2 | c.1361A>T p.Y454F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2
- IKZF2 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNH7 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KRTAP12-4 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB3 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MARF1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MYH9 | c.158_168del p.E53Gfs*15 | Frame Shift Del (DEL) | VAF 35/299 reads (12%) | called by mutect2, pindel, varscan2
- NCOA3 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.023); called by muse, mutect2
- NFKBIZ | c.2139G>C p.Q713H | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- NOX4 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OPHN1 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- OR10A2 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR51T1 | c.760T>A p.Y254N | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PCDHGB3 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PHLPP1 | c.1276C>G p.P426A | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLD4 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PTPN18 | c.846G>C p.R282S | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RAB6B | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); called by muse, mutect2
- SAXO1 | c.1162A>C p.S388R | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2
- SCN11A | c.2949G>A p.K983= | Splice Region (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SCN11A | c.2948A>T p.K983M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC15A2 | c.1870A>T p.M624L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- SLITRK2 | c.1612A>T p.M538L | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SRFBP1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYMPK | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TF | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TKTL2 | c.233A>T p.H78L | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- TMC2 | c.2403G>C p.K801N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TNRC6A | c.1596C>A p.D532E | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNRC6C | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TRPS1 | c.3641C>T p.S1214L (on ENST00000220888 / NM_001330599.2; = p.S1227L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/473 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- UGGT1 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- VNN3 | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDFY3 | c.8035G>C p.E2679Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZFP36 | c.430C>G p.R144G (on ENST00000594442; = p.R138G on NM_003407.5) | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF552 | c.986_998del p.C329Lfs*91 | Frame Shift Del (DEL) | VAF 29/240 reads (12%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.18C>T p.T6= | Silent (SNP) | VAF 14/118 reads (12%) | called by mutect2, varscan2
- C1orf112 | c.1467A>G p.G489= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- CCER1 | c.648G>A p.A216= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as rs1295769498, COSV62646310; called by muse, mutect2
- CDHR2 | c.213T>C p.A71= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- CLCN1 | c.2301C>A p.I767= | Silent (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- COL4A6 | c.2601C>T p.G867= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV57863990; called by muse, mutect2
- CR1 | c.4710C>T p.S1570= | Silent (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- CTNND1 | c.1824C>G p.A608= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.6745T>C p.L2249= | Silent (SNP) | VAF 21/189 reads (11%) | called by muse, varscan2
- ELANE | c.567C>G p.L189= | Silent (SNP) | VAF 50/498 reads (10%) | catalogued as CS135443; called by muse, mutect2, varscan2
- F2R | c.741C>G p.P247= | Silent (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- KRTAP6-1 | c.36C>A p.T12= | Silent (SNP) | VAF 30/292 reads (10%) | catalogued as COSV58167981, COSV58168644; called by muse, mutect2, varscan2
- MCF2L2 | c.768A>G p.L256= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- NFIB | c.306G>A p.P102= | Silent (SNP) | VAF 28/263 reads (11%) | catalogued as rs772662135, COSV66620507; called by muse, mutect2, varscan2
- OR6T1 | c.456A>T p.G152= | Silent (SNP) | VAF 11/268 reads (4%) | catalogued as COSV58306976; called by muse, mutect2
- PPP1R13L | c.2256G>A p.E752= | Silent (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- PRKAG1 | c.39G>A p.V13= | Silent (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- PRSS16 | c.906G>A p.T302= | Silent (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- SLC25A43 | c.183G>T p.R61= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- SMPD2 | c.417C>T p.A139= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as rs749295859; called by muse, mutect2, varscan2
- TARS3 | c.2241T>C p.A747= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- TNFRSF10A | c.1182C>T p.I394= | Silent (SNP) | VAF 29/248 reads (12%) | catalogued as rs776854767, COSV99646140; called by muse, mutect2, varscan2
- TRPC5 | c.1443C>G p.L481= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs771289425; called by muse, mutect2, varscan2
- ZNF281 | c.141C>T p.P47= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as rs1015477248; called by muse, mutect2
- ZNF585B | c.1347C>A p.S449= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as COSV57216519; called by muse, mutect2
- AGPAT3 | c.-48-4455G>C | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1388T>G | Intron (SNP) | VAF 25/224 reads (11%) | catalogued as COSV100341901; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503972 del AAT | 5'Flank (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- DDX11L8 | n.108A>G | RNA (SNP) | VAF 24/657 reads (4%) | called by muse, mutect2
- DPP6 | c.*250G>A | 3'UTR (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- DPY30 | chr2:32023472 C>T | 3'Flank (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- FCRL2 | c.884-30C>A | Intron (SNP) | VAF 18/274 reads (7%) | catalogued as rs1223004559, COSV63835493; called by muse, mutect2
- FCRL3 | c.*1941G>T | 3'UTR (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- FRMD1 | chr6:168081364 G>C | 5'Flank (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- HYDIN | c.11471+846G>T | Intron (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- LRIG3 | c.3115+29G>A | Intron (SNP) | VAF 11/93 reads (12%) | catalogued as rs746482468; called by muse, mutect2, varscan2
- TMEM19 | c.-2C>G | 5'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- TNFAIP2 | c.-663-665G>A | Intron (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- U3 | chr15:69461769 G>A | 5'Flank (SNP) | VAF 7/19 reads (37%) | catalogued as rs1278947006; called by muse, mutect2, varscan2
- WDR83OS | c.-5T>C | 5'UTR (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
